Somatic mutation profile of tumor specimen MMRF_1293_3_BM_CD138pos (aliquot MMRF_1293_3_BM_CD138pos_T1_KHS5U_L12902) from MMRF case MMRF_1293, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.4 years (21,678 days).
Specimen MMRF_1293_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2044c59f-c619-4a6f-9c6e-a2b08200e61a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1293_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1293_2_PB_WBC_C1_KBS5U_L05569; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07a7c24a-a723-48f9-b743-be28bec3bf23

The open-access MAF lists 102 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 31, Intron 13, Silent 12, Nonsense Mutation 4, Splice Region 2, 5'Flank 2, 3'Flank 1, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 39/233 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); catalogued as rs775569138, COSV50987018; called by muse, mutect2, varscan2
- ACTL9 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs782533493, COSV61005098, COSV61006897; called by muse, mutect2, varscan2
- ANK2 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764760708, COSV52170121, COSV52188897; called by muse, mutect2, varscan2
- ATG9B | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1193140397; called by muse, mutect2, varscan2
- BICD1 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs183425481, COSV55675098; called by muse, mutect2, varscan2
- CCDC18 | c.3839G>C p.R1280T (on ENST00000343253 / NM_001306076.1; = p.R1281T on NM_206886.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs757562852; called by muse, mutect2, varscan2
- CDKL5 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs1413837885; called by muse, mutect2, varscan2
- CSMD3 | c.3427C>A p.P1143T (on ENST00000297405 / NM_001363185.1; = p.P1039T on NM_052900.3) | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52093613; called by muse, mutect2, varscan2
- H1-4 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799905, COSV56803909; called by muse, mutect2, varscan2
- HTR2C | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV52221996; called by muse, mutect2, varscan2
- IGHJ4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 32/61 reads (52%) | PolyPhen benign (0.014); catalogued as rs555110696; called by muse, mutect2, varscan2
- IRX4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs754848816, COSV51474073; called by muse, mutect2, varscan2
- MTO1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757887848; called by muse, mutect2, varscan2
- PGAP2 | c.419-3C>T | Splice Region (SNP) | VAF 80/536 reads (15%) | catalogued as rs202073184; called by muse, mutect2, varscan2
- PPP2CB | c.443A>C p.D148A | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV55327989; called by muse, mutect2, varscan2
- SCUBE1 | c.484+1G>T p.X162_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV51815538; called by mutect2, varscan2
- SOGA3 | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369861960; called by muse, mutect2, varscan2
- TAS2R1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs145804099, COSV101225699; called by muse, mutect2, varscan2
- TGM4 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs202075944; called by muse, mutect2, varscan2
- ZCCHC3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779001468; called by muse, varscan2
- ATP13A5 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CACNA1S | c.4201G>T p.E1401* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- CGA | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CHIA | c.927C>A p.F309L (on ENST00000343320; = p.F201L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CLPTM1L | c.172T>G p.Y58D | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DGKB | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HFM1 | c.2434T>A p.L812M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IDE | c.1153+7A>C | Splice Region (SNP) | VAF 32/126 reads (25%) | called by muse, varscan2
- IGHV2-70 | c.118_135del p.T40_G45del | In Frame Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- KLKB1 | c.705del p.N236Tfs*47 | Frame Shift Del (DEL) | VAF 26/188 reads (14%) | called by pindel, varscan2
- MAGI1 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- MED14 | c.1315G>C p.V439L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METAP2 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2
- MUC3A | c.8008A>G p.T2670A | Missense Mutation (SNP) | VAF 60/606 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PARD3 | c.3628G>T p.E1210* | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- PCNX1 | c.4787T>G p.L1596* | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1106A>C p.N369T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCAL1 | c.1556T>G p.L519R | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SPINK5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ZAN | c.1733G>C p.S578T | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ZNF169 | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.4335C>G p.S1445= | Silent (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- ETFB | c.699C>T p.R233= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- GRB10 | c.1050C>T p.G350= (on ENST00000398812; = p.G304= on NM_001001549.3) | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- IGHD2-2 | c.22C>T p.L8= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs781865993; called by muse, mutect2, varscan2
- IGKC | c.150T>G p.G50= | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, varscan2
- KCNC1 | c.249C>T p.C83= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56391450; called by muse, mutect2, varscan2
- KRT5 | c.507C>T p.R169= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs200658792, COSV52859976; called by muse, mutect2, varscan2
- MMP2 | c.306C>T p.C102= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as rs201679510, CM161166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR1M1 | c.477C>T p.H159= | Silent (SNP) | VAF 79/449 reads (18%) | catalogued as rs551740717; called by muse, mutect2, varscan2
- PRDM10 | c.2892T>C p.D964= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- RFNG | c.435G>C p.V145= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- TFPT | c.450C>T p.A150= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- ABL2 | c.*5243T>A | 3'UTR (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- AGBL3 | c.2343-5715T>G | Intron (SNP) | VAF 35/136 reads (26%) | catalogued as rs537988721; called by muse, mutect2
- AGBL5 | c.*348T>G | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF15 | c.*1360C>A | 3'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- BMP6 | c.*1184_*1186del | 3'UTR (DEL) | VAF 20/72 reads (28%) | called by pindel, varscan2
- BRWD1 | c.6571+3215T>C | Intron (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- C11orf71 | c.343+158T>G | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- C11orf71 | c.343+61T>C | Intron (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- C6orf141 | c.*148+371T>C | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- CACNA1B | c.*1510G>T | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- CADM2 | c.*23T>C | 3'UTR (SNP) | VAF 61/317 reads (19%) | catalogued as rs1388231729; called by muse, mutect2, varscan2
- CHCHD6 | c.411+47190G>A | Intron (SNP) | VAF 8/204 reads (4%) | catalogued as COSV52070718; called by muse, mutect2
- DPP6 | c.*612A>T | 3'UTR (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- DUSP6 | chr12:89353214 ins T | 5'Flank (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- EBF1 | c.*458A>T | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs34622170, COSV58166185, COSV58173725; called by muse, varscan2
- EPCAM | c.76+85T>C | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- GLO1 | c.*885A>G | 3'UTR (SNP) | VAF 25/149 reads (17%) | catalogued as rs1329038617; called by muse, mutect2, varscan2
- GOLGA1 | c.*4G>A | 3'UTR (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- HIBCH | c.*105A>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- HLA-A | c.*148del | 3'UTR (DEL) | VAF 41/279 reads (15%) | called by pindel, varscan2
- HPS5 | c.3329+11T>C | Intron (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- IL17D | c.*279A>G | 3'UTR (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- INSC | c.*761T>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- KLF13 | c.*3046A>G | 3'UTR (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- KLF3 | c.*2020G>A | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851262 C>G | 5'Flank (SNP) | VAF 22/166 reads (13%) | called by muse, varscan2
- MSR1 | c.1033+3906dup | Intron (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- NDUFAF1 | c.759+611C>T | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- NIT1 | chr1:161125366 G>T | 3'Flank (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- NLRC5 | c.4154+224A>T | Intron (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- OTX1 | c.*214G>A | 3'UTR (SNP) | VAF 26/117 reads (22%) | catalogued as rs1035097087; called by muse, mutect2, varscan2
- PDE4DIP | c.518+229G>T | Intron (SNP) | VAF 22/375 reads (6%) | called by muse, mutect2
- PLXNA4 | c.*6937del | 3'UTR (DEL) | VAF 11/48 reads (23%) | catalogued as rs200299501; called by mutect2, varscan2
- RCE1 | c.*242G>A | 3'UTR (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- RNF115 | c.*420A>G | 3'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as rs1197904396; called by muse, mutect2, varscan2
- RPS10 | c.*423C>T | 3'UTR (SNP) | VAF 29/202 reads (14%) | called by muse, mutect2, varscan2
- RPTN | c.*777G>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- SEMA3E | c.*3279C>A | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2
- SRRM4 | c.*1733C>T | 3'UTR (SNP) | VAF 35/126 reads (28%) | catalogued as rs1419700230; called by muse, mutect2, varscan2
- STC2 | c.506+76G>A | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as rs767834711; called by muse, mutect2, varscan2
- SYNPO2L | c.*284C>T | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- TMEM33 | c.*1593A>G | 3'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- TTC9 | c.*3338G>A | 3'UTR (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8114dup | 3'UTR (INS) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB42 | c.*608_*609insCG | 3'UTR (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- ZNF141 | c.*9378A>T | 3'UTR (SNP) | VAF 26/127 reads (20%) | called by muse, varscan2
- ZNF24 | c.*4478T>G | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
